Somatic mutation profile of tumor specimen TCGA-AG-A008-01A (aliquot TCGA-AG-A008-01A-01W-A00K-09) from TCGA case TCGA-AG-A008, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 50.4 years (18,416 days).
Specimen TCGA-AG-A008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0d2e901-fd71-49a6-9c91-959bb0917795.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A008-10A (Blood Derived Normal), aliquot TCGA-AG-A008-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/904015be-3826-4c8d-b163-35e1ba1b2869

The open-access MAF lists 85 somatic variants for this specimen: 68 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Frame Shift Del 6, Nonsense Mutation 6, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 46/102 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 121/149 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519741, COSV61684436, COSV61688043; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACKR2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 293/604 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.11); catalogued as rs764776544; called by muse, mutect2, varscan2
- AKR1D1 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 49/185 reads (26%) | catalogued as COSV54336408; called by muse, mutect2, varscan2
- APC | c.4476del p.T1493Rfs*14 | Frame Shift Del (DEL) | VAF 151/383 reads (39%) | catalogued as COSV57375363; called by mutect2, pindel, varscan2
- ATG16L1 | c.1313G>A p.R438H (on ENST00000392017 / NM_030803.7; = p.R419H on NM_017974.4) | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs1384387635, COSV61464087; called by muse, mutect2, varscan2
- CCDC103 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1477668851; called by muse, mutect2
- CCDC85A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs554353955, COSV68151378; called by muse, mutect2, varscan2
- CKAP5 | c.4358G>A p.R1453H | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs1226299807; called by muse, mutect2, varscan2
- CMYA5 | c.11087A>T p.D3696V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV71406718; called by muse, mutect2, varscan2
- CNTNAP2 | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 51/184 reads (28%) | catalogued as rs771533907, COSV100662227; called by muse, mutect2, varscan2
- CPXCR1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs191294021, COSV52161454, COSV52162365; called by muse, mutect2, varscan2
- CXCR4 | c.53del p.S18* | Frame Shift Del (DEL) | VAF 39/100 reads (39%) | catalogued as COSV54013440; called by mutect2, pindel, varscan2
- DNAH7 | c.8665C>T p.R2889* | Nonsense Mutation (SNP) | VAF 104/253 reads (41%) | catalogued as rs1179296507, COSV100417331; called by muse, mutect2, varscan2
- EPHA5 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56641973, COSV99900317; called by muse, mutect2, varscan2
- GRIP1 | c.1801G>A p.V601I (on ENST00000359742 / NM_001379345.1; = p.V549I on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/320 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199936956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH7 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59797768; called by muse, mutect2, varscan2
- LRP1B | c.6814G>A p.E2272K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1279445028; called by muse, mutect2
- MAP3K21 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64044616; called by muse, mutect2, varscan2
- NAA10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1557107264; called by muse, mutect2
- NKAIN3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs765524369, COSV60654926; called by muse, mutect2, varscan2
- OR6K2 | c.855C>G p.F285L | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.05); catalogued as COSV62743919; called by muse, mutect2, varscan2
- PLXNC1 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs753617960; called by muse, mutect2, varscan2
- PXN | c.442del p.L148Cfs*5 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as COSV99935905; called by mutect2, pindel, varscan2
- RBM10 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61311090; called by muse, mutect2, varscan2
- SEC23IP | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs776224093; called by muse, mutect2, varscan2
- SEC24B | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs765040358; called by muse, mutect2, varscan2
- SEPTIN2 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV100764928; called by muse, mutect2
- SOX9 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV55423080; called by muse, mutect2, varscan2
- SYN3 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753833714, COSV60502626; called by muse, mutect2, varscan2
- TARBP1 | c.2072G>T p.C691F | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs770281284; called by muse, mutect2, varscan2
- TBC1D9B | c.2026C>T p.L676F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs905517567; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs745872748; called by mutect2, varscan2
- TIMP1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as rs140600134, COSV99512074; called by muse, mutect2, varscan2
- TMPRSS11A | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs187902089; called by muse, mutect2, varscan2
- TUBA1C | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.498); catalogued as rs1479463024; called by muse, mutect2, varscan2
- UNC5D | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773478021, COSV54776215, COSV99771084; called by muse, mutect2, varscan2
- VSIG4 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs752906800, COSV104425187; called by muse, mutect2, varscan2
- XKR6 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.914); catalogued as rs758968294, COSV100441169; called by muse, mutect2, varscan2
- ZC3H6 | c.588dup p.Q197Tfs*11 | Frame Shift Ins (INS) | VAF 33/75 reads (44%) | catalogued as rs750386324; called by mutect2, varscan2
- ZIC4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs766045409, COSV67170511, COSV67172399; called by muse, mutect2, varscan2
- ZNF208 | c.1920A>C p.K640N | Missense Mutation (SNP) | VAF 121/520 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.217); catalogued as COSV68102084; called by muse, mutect2, varscan2
- ZNF354A | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59983732; called by muse, mutect2, varscan2
- ABL2 | c.2761C>T p.P921S (on ENST00000502732 / NM_007314.4; = p.P906S on NM_005158.5) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP9 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- APC | c.3253A>T p.K1085* | Nonsense Mutation (SNP) | VAF 132/293 reads (45%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT3 | c.664T>G p.F222V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAG1 | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CCL2 | c.259del p.M87Wfs*25 | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | called by mutect2, pindel, varscan2
- COL5A2 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DGKD | c.347C>T p.T116M (on ENST00000264057 / NM_152879.3; = p.T72M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DPP9 | c.782C>T p.T261I (on ENST00000598800; = p.T290I on NM_139159.5) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.102); called by muse, mutect2
- GLUD2 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HEY1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF1 | c.3933A>T p.E1311D | Missense Mutation (SNP) | VAF 35/551 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- IRAG2 | c.3739C>T p.P1247S (on ENST00000636465; = p.P292S on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MBOAT2 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MUC16 | c.21015G>C p.L7005F | Missense Mutation (SNP) | VAF 145/728 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MYF5 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 64/146 reads (44%) | called by muse, mutect2, varscan2
- OR52M1 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- PCDHGC5 | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDC1 | c.265del p.S89Pfs*17 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- SRRM1 | c.1229A>G p.K410R | Missense Mutation (SNP) | VAF 101/115 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SYNJ1 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132E | c.1246G>A p.G416R (on ENST00000321639; = p.G506R on NM_001304438.2) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTRN | c.8296C>A p.P2766T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ATP10A | c.3591C>T p.N1197= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as rs1008252585, COSV63513249; called by muse, mutect2, varscan2
- CAMTA1 | c.2895C>T p.H965= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as rs748465246, COSV57885845; called by muse, mutect2
- CHD7 | c.8088T>C p.P2696= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV71112097; called by muse, mutect2
- FAT2 | c.5464C>T p.L1822= | Silent (SNP) | VAF 49/253 reads (19%) | catalogued as rs749649560, COSV55822267; called by muse, mutect2, varscan2
- FBXO8 | c.306G>A p.A102= | Silent (SNP) | VAF 79/131 reads (60%) | catalogued as rs763345340, COSV67031704; called by muse, mutect2, varscan2
- GATAD2A | c.306C>T p.D102= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1268970753; called by muse, mutect2, varscan2
- KAT6B | c.4779G>A p.Q1593= | Silent (SNP) | VAF 95/338 reads (28%) | catalogued as COSV54749504; called by muse, mutect2, varscan2
- MUC5B | c.12975C>T p.P4325= | Silent (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- MYPN | c.1623C>T p.N541= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as rs746849244; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFATC3 | c.421T>C p.L141= | Silent (SNP) | VAF 140/290 reads (48%) | catalogued as rs1204999384, COSV60475245; called by muse, mutect2, varscan2
- TBX20 | c.951C>T p.Y317= | Silent (SNP) | VAF 45/72 reads (63%) | catalogued as rs113335362; called by muse, mutect2, varscan2
- TNC | c.5532G>A p.T1844= | Silent (SNP) | VAF 94/232 reads (41%) | catalogued as rs200409463, COSV60786153; called by muse, mutect2, varscan2
- U2SURP | c.1098G>A p.P366= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs370500835; called by muse, mutect2, varscan2
- ZNF366 | c.231G>A p.R77= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV59216443; called by muse, mutect2, varscan2
- ZNF544 | c.135G>A p.E45= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV54136495; called by muse, mutect2, varscan2
- FERMT1 | c.*706C>T | 3'UTR (SNP) | VAF 17/21 reads (81%) | catalogued as rs757795824; called by muse, mutect2, varscan2
- ZNF658B | n.2193A>G | RNA (SNP) | VAF 208/963 reads (22%) | called by muse, mutect2, varscan2
